FM case AD14083 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/1a19f2d8-b4d5-4a81-8907-fd5a713d888d

Male, 75.2 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the stomach; metastasis biopsied or resected from the bladder. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
